Somatic mutation profile of tumor specimen 0DGDWE from CCDI case PBBSZP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.8 years (286 days).
Specimen 0DGDWE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f80a778-4765-435a-80c9-856adde179be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGDW1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71bf76c1-6128-4732-8e31-e13b5f3541df

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB3 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 40/908 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs766370904; called by muse, mutect2
- CORO7 | c.780G>A p.S260= | Silent (SNP) | VAF 12/274 reads (4%) | catalogued as rs764490402; called by muse, mutect2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, varscan2
- TK1 | chr17:78187071 C>T | 5'Flank (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
